FM case AD13239 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon.
https://portal.gdc.cancer.gov/cases/b543deb0-1216-4ec7-9e9b-c52a9cfbc859

Female, 64.9 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the colon; primary biopsied or resected from the colon. Tumor nuclei on the sequenced sample's slide: 40% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
